Somatic mutation profile of tumor specimen TCGA-13-1403-01A (aliquot TCGA-13-1403-01A-01W-0494-09) from TCGA case TCGA-13-1403, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.5 years (17,697 days).
Specimen TCGA-13-1403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fb37f66-ab78-4c2e-b828-74b514a0bc33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1403-10A (Blood Derived Normal), aliquot TCGA-13-1403-10A-01W-0493-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c63e6606-4653-4e94-933c-d94652a71cfd

The open-access MAF lists 54 somatic variants for this specimen: 48 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 39, Silent 6, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 131/165 reads (79%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ACTRT1 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 125/321 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV64419850; called by muse, mutect2, varscan2
- ADCY5 | c.3164G>A p.R1055H | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs762578500, COSV59201616; called by muse, mutect2, varscan2
- ANGPTL5 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.748); catalogued as COSV57534200; called by muse, mutect2, varscan2
- ATP10A | c.3254T>A p.L1085H | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100791417; called by muse, mutect2
- CABS1 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 93/124 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56734289; called by muse, mutect2, varscan2
- CDKN1A | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs201631722, COSV55189416; called by muse, mutect2, varscan2
- CNTNAP4 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100272705; called by muse, mutect2
- CSNK1E | c.516C>A p.N172K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV63291912; called by muse, mutect2, varscan2
- DTD1 | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV66281448; called by muse, mutect2, varscan2
- ERC2 | c.839T>A p.L280* | Nonsense Mutation (SNP) | VAF 274/604 reads (45%) | catalogued as COSV55651354; called by muse, mutect2, varscan2
- FAM217B | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 84/171 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs761762507, COSV62564936; called by muse, mutect2, varscan2
- FAM83D | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54158432; called by muse, mutect2, varscan2
- FLG2 | c.3356G>T p.G1119V | Missense Mutation (SNP) | VAF 146/561 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV66171612; called by muse, mutect2, varscan2
- GABRA2 | c.856+1G>T p.X286_splice | Splice Site (SNP) | VAF 60/521 reads (12%) | catalogued as COSV62918132; called by muse, mutect2, varscan2
- GALNT17 | c.1299A>C p.E433D | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV61182128; called by muse, mutect2, varscan2
- GLRA2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV54336084, COSV54349118; called by muse, mutect2, varscan2
- GRM7 | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV63137545, COSV63161207; called by muse, mutect2, varscan2
- ITGA8 | c.2684G>A p.R895Q | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs368464139; called by muse, mutect2, varscan2
- KCNE1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as rs1555844239, COSV61607291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAIR1 | c.612G>C p.Q204H | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV57309123; called by muse, mutect2, varscan2
- LRFN2 | c.1750C>G p.P584A | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as rs1267164315, COSV57832554; called by muse, mutect2, varscan2
- MED12L | c.6091G>T p.V2031L | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV56391791; called by muse, mutect2, varscan2
- MEGF10 | c.3383G>C p.S1128T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV57254462; called by muse, mutect2, varscan2
- MLIP | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs756118536, COSV51434825; called by muse, mutect2, varscan2
- MMGT1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 52/940 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs782263638, COSV100018660; called by muse, mutect2
- MSL1 | c.1065A>C p.K355N (on ENST00000398532 / NM_001365919.1; = p.K92N on NM_001012241.2) | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as COSV100278193; called by muse, mutect2
- MYCBP2 | c.6125G>C p.G2042A (on ENST00000357337; = p.G2080A on NM_015057.5) | Missense Mutation (SNP) | VAF 229/250 reads (92%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV62033540; called by muse, mutect2, varscan2
- NSUN2 | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 174/280 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs190753127; called by muse, mutect2, varscan2
- P2RY2 | c.379A>T p.I127F | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60777382; called by muse, mutect2, varscan2
- PCOLCE2 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 162/351 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56001176; called by muse, mutect2, varscan2
- POLA1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs760605087, COSV66889543; called by muse, mutect2, varscan2
- SGK3 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61895132, COSV61896180; called by muse, varscan2
- SLC41A2 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV51609275; called by muse, mutect2, varscan2
- SNTG1 | c.1434C>A p.C478* | Nonsense Mutation (SNP) | VAF 121/307 reads (39%) | catalogued as COSV52463328; called by muse, mutect2, varscan2
- STAM | c.353A>G p.E118G | Missense Mutation (SNP) | VAF 127/258 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV66325770; called by muse, mutect2, varscan2
- SUGCT | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 130/220 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59346568; called by muse, mutect2
- TAS2R1 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66779221; called by muse, mutect2, varscan2
- TTN | c.48244G>A p.V16082I (on ENST00000591111; = p.V8658I on NM_003319.4) | Missense Mutation (SNP) | VAF 499/1075 reads (46%) | PolyPhen benign (0.332); catalogued as COSV60256732; called by muse, mutect2, varscan2
- UGT3A2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs200458466, COSV56929077; called by muse, mutect2, varscan2
- VCPKMT | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs754454175, COSV99366595; called by muse, mutect2, varscan2
- YBEY | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59310937; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 112/233 reads (48%) | catalogued as COSV56274011; called by muse, mutect2, varscan2
- KRT16 | c.1040T>A p.L347Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A2 | c.415_458del p.I139Efs*16 | Frame Shift Del (DEL) | VAF 96/257 reads (37%) | called by mutect2, pindel
- PASK | c.1176_1205del p.M392_L402delinsI | In Frame Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- PDE6C | c.900_905del p.V301_E302del | In Frame Del (DEL) | VAF 44/111 reads (40%) | called by mutect2, pindel, varscan2
- RNF17 | c.1741_1758+11del p.X581_splice | Splice Site (DEL) | VAF 40/76 reads (53%) | called by mutect2, pindel, varscan2
- ADAM12 | c.285G>A p.T95= | Silent (SNP) | VAF 68/150 reads (45%) | catalogued as rs777524851, COSV64112122; called by muse, mutect2, varscan2
- CACNA1E | c.6489G>T p.P2163= (on ENST00000367573 / NM_001205293.3; = p.P2120= on NM_000721.4) | Silent (SNP) | VAF 44/91 reads (48%) | catalogued as rs377180948, COSV62388209; called by muse, mutect2, varscan2
- CENPF | c.918A>G p.K306= | Silent (SNP) | VAF 81/179 reads (45%) | catalogued as COSV65277914; called by muse, mutect2, varscan2
- KIAA0100 | c.4032C>T p.G1344= | Silent (SNP) | VAF 20/269 reads (7%) | catalogued as rs1158304420, COSV101197377; called by muse, mutect2
- OR4D11 | c.537C>T p.C179= | Silent (SNP) | VAF 180/422 reads (43%) | catalogued as rs374819635; called by muse, mutect2, varscan2
- PCDHGB6 | c.1344C>T p.N448= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs775680397, COSV53920230; called by muse, mutect2, varscan2
